Somatic mutation profile of tumor specimen TARGET-10-PARGGI-09A (aliquot TARGET-10-PARGGI-09A-01D) from TARGET case TARGET-10-PARGGI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.2 years (3,708 days).
Specimen TARGET-10-PARGGI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1174476b-31b4-4765-a13e-7741390dfdce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGGI-10A (Blood Derived Normal), aliquot TARGET-10-PARGGI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b642b59d-c553-4269-ac14-e1bc4a73e461

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRLF2 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1057519743, COSV67493408; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCHS1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs543316074, COSV55032532; called by muse, mutect2, varscan2
- DMD | c.2579C>T p.P860L | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs754502808; called by muse, mutect2, varscan2
- GAS2L3 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs373555854, COSV57157784; called by muse, mutect2, varscan2
- LY9 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54435899; called by muse, mutect2, varscan2
- MEI1 | c.3736C>T p.P1246S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV55387670; called by muse, mutect2
- PLCE1 | c.2965G>A p.V989M | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs763441024, COSV53357248; called by muse, mutect2, varscan2
- RFPL4AL1 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.226); catalogued as COSV59113097; called by muse, mutect2
- SYNJ1 | c.3705G>A p.P1235= | Splice Region (SNP) | VAF 31/71 reads (44%) | catalogued as rs1160685381, COSV100449361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF33 | c.2523T>A p.N841K | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ASXL3 | c.4732A>T p.N1578Y | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- LATS2 | c.2288_2289insAAGG p.F763Lfs*4 | Frame Shift Ins (INS) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- NUTM1 | c.1609C>A p.H537N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SNX12 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIPI | c.825G>A p.Q275= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- RPF2 | c.640T>C p.L214= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- RTL5 | c.936C>T p.R312= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as rs1043461984, COSV65453054; called by muse, mutect2
- IGLV4-69 | chr22:22031472 ins GGC | 3'Flank (INS) | VAF 24/83 reads (29%) | called by mutect2, pindel, varscan2
- TENM1 | c.4084-9G>A | Intron (SNP) | VAF 39/89 reads (44%) | catalogued as rs376202433; called by muse, mutect2, varscan2
- TUBGCP2 | c.*129C>T | 3'UTR (SNP) | VAF 23/60 reads (38%) | catalogued as rs1307682901; called by muse, mutect2, varscan2
